Somatic mutation profile of tumor specimen TCGA-CV-7247-01A (aliquot TCGA-CV-7247-01A-11D-2012-08) from TCGA case TCGA-CV-7247, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 55.9 years (20,433 days).
Specimen TCGA-CV-7247-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb7124d7-3a93-4c99-a777-cf15fccbe304.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7247-10A (Blood Derived Normal), aliquot TCGA-CV-7247-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7f36e30-c002-4922-9289-efa28e2877dd

The open-access MAF lists 65 somatic variants for this specimen: 53 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 11, Frame Shift Del 7, Nonsense Mutation 4, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.4039C>T p.R1347C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53980840; called by muse, mutect2, varscan2
- ALG1 | c.552C>A p.F184L | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52158155, COSV99275955; called by muse, mutect2, varscan2
- AP3D1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100642925; called by muse, mutect2
- ASPN | c.266C>G p.S89* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV65016072, COSV65016561; called by muse, mutect2, varscan2
- C10orf95 | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99493800; called by muse, mutect2, varscan2
- CACNA1C | c.81T>A p.H27Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.188); catalogued as COSV100221378; called by muse, varscan2
- CDK11B | c.1484C>A p.P495H | Missense Mutation (SNP) | VAF 25/280 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV58341588; called by muse, mutect2
- CERKL | c.937C>T p.P313S (on ENST00000339098 / NM_001030311.2; = p.P287S on NM_201548.5) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.018); catalogued as COSV59204610; called by muse, mutect2, varscan2
- CPA4 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99745265; called by muse, mutect2, varscan2
- CTNNA2 | c.2110T>G p.W704G | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100561735; called by muse, mutect2, varscan2
- DCC | c.3360T>G p.I1120M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV101473440; called by muse, mutect2, varscan2
- DOP1A | c.1430A>T p.D477V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.997); catalogued as COSV99382674; called by muse, mutect2, varscan2
- ETV6 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 62/445 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs201820837, COSV67148091, COSV67150412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM110B | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100826246; called by muse, mutect2
- FRMPD4 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV101043763; called by muse, mutect2
- H2BC7 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs932144912, COSV100587250; called by muse, mutect2, varscan2
- HEATR5B | c.2085A>C p.E695D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV99250029; called by muse, mutect2, varscan2
- HTR3D | c.409G>T p.A137S (on ENST00000382489 / NM_001163646.2; = p.A2S on NM_182537.3) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV100488249; called by muse, mutect2, varscan2
- LAMA1 | c.1094T>G p.L365W | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV101057367; called by muse, mutect2, varscan2
- MAN1C1 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV56044871; called by muse, mutect2, varscan2
- MINAR1 | c.2101A>T p.K701* | Nonsense Mutation (SNP) | VAF 12/122 reads (10%) | catalogued as COSV59582948; called by muse, mutect2, varscan2
- MYH2 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759145892, COSV55449960; called by mutect2, varscan2
- NCAN | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs753950202, COSV99388032; called by muse, mutect2, varscan2
- PAPPA2 | c.1218G>T p.L406F | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); catalogued as COSV62787144; called by muse, mutect2, varscan2
- PCCA | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.189); catalogued as COSV100887011; called by muse, mutect2, varscan2
- PCDHB1 | c.1351A>T p.I451L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100128334; called by muse, mutect2, varscan2
- PDE3A | c.3198C>G p.F1066L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.108); catalogued as COSV62977213; called by muse, mutect2
- PDE6C | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.243); catalogued as COSV101008829; called by muse, mutect2, varscan2
- PSG8 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100126532; called by muse, mutect2, varscan2
- PYDC2 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV101573365; called by muse, mutect2
- SMTN | c.1803C>A p.D601E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV100294818; called by muse, mutect2, varscan2
- SRPRB | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV99558203; called by muse, mutect2
- SRRT | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53816098; called by muse, mutect2, varscan2
- STK33 | c.1347T>G p.S449= | Splice Region (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100174373; called by muse, mutect2, varscan2
- STK39 | c.527T>G p.V176G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100597077; called by muse, mutect2
- STRADA | c.1071G>T p.E357D (on ENST00000336174 / NM_001363786.1; = p.E320D on NM_153335.6) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV99368697; called by muse, mutect2, varscan2
- STXBP4 | c.1393A>C p.T465P | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV100894837; called by muse, mutect2
- SULF1 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.767); catalogued as rs201229545, COSV52676815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TOP2A | c.3570A>C p.Q1190H | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as COSV101396345; called by muse, mutect2
- TRGV9 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.447); catalogued as rs756459413; called by muse, mutect2, varscan2
- TRIM48 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as rs1368164210, COSV101338340; called by muse, mutect2, varscan2
- USH2A | c.3298G>C p.E1100Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.342); catalogued as COSV100240230; called by muse, mutect2, varscan2
- USP33 | c.833G>A p.C278Y | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100657196; called by muse, mutect2, varscan2
- ZNF440 | c.1506del p.F502Lfs*4 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs1450430385; called by mutect2, pindel, varscan2
- ZNF823 | c.1376A>C p.Q459P (on ENST00000341191 / NM_001297610.2; = p.Q415P on NM_017507.2) | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100362598; called by muse, mutect2
- CLSTN2 | c.843del p.S282Afs*73 | Frame Shift Del (DEL) | VAF 59/180 reads (33%) | called by mutect2, pindel, varscan2
- EIF4G2 | c.2163_2167del p.K722Tfs*29 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- HECTD1 | c.4938del p.S1647Vfs*59 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | called by mutect2, pindel, varscan2
- KANSL1 | c.1450_1462delinsTA p.E484Yfs*12 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by pindel, varscan2*
- PAN2 | c.2216del p.D739Vfs*9 (on ENST00000425394 / NM_001127460.3; = p.D735Vfs*9 on NM_014871.5) | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- PTDSS1 | c.910del p.T304Pfs*4 | Frame Shift Del (DEL) | VAF 59/164 reads (36%) | called by mutect2, pindel, varscan2
- QPCT | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.838); called by muse, mutect2
- ACO2 | c.1473G>A p.T491= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs148997312; ClinVar: likely benign; called by muse, mutect2
- AXIN2 | c.2487G>A p.P829= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs768793839, COSV61059566; ClinVar: likely benign; called by muse, mutect2, varscan2
- CILP2 | c.1902G>A p.L634= | Silent (SNP) | VAF 9/148 reads (6%) | catalogued as COSV99365062; called by muse, mutect2
- GLOD5 | c.351C>T p.H117= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as rs1557017334, COSV100297519; called by muse, mutect2, varscan2
- HEATR1 | c.687A>G p.V229= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV63982824, COSV63983928; called by muse, mutect2, varscan2
- PKD1 | c.5625C>G p.V1875= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs751502749, COSV51913865, COSV99238812; called by muse, mutect2, varscan2
- PPOX | c.1095G>A p.V365= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99237691; called by muse, mutect2, varscan2
- PRKAA2 | c.183A>C p.I61= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV100983018; called by muse, mutect2, varscan2
- THSD7A | c.3165G>C p.V1055= | Silent (SNP) | VAF 18/368 reads (5%) | catalogued as COSV101448844; called by muse, mutect2
- USF3 | c.1779C>G p.L593= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV100325660; called by muse, mutect2, varscan2
- ZRANB3 | c.2784G>A p.A928= | Silent (SNP) | VAF 28/232 reads (12%) | catalogued as rs202125924, COSV51501068; called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28579788 C>A | 3'Flank (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
